Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5892, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5892-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Left renal mass >6 cm

Specimens Submitted:

- 1: SP: Kidney, left, total nephrectomy
- 2: SP: Lymph nodes, pre-aortic and para-aortic, dissection
- 3: SP: Adrenal gland and suprahilar lymph node, left, excision
- 4: SP: Lymph nodes, left hilar, dissection

DIAGNOSIS:

1. SP: Kidney, left, total nephrectomy:

Tumor Type:

Renal cell carcinoma - Unclassified type

Angiomyolipoma, 1 cm in greatest dimension. SEE COMMENT

Fuhrman Nuclear Grade:

High nuclear grade

Tumor Size:

Greatest diameter is 6.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

The renal artery exhibits moderate atherosclerotic changes with stenosis at the margin

Non-Neoplastic Kidney:

Mild arterionephrosclerosis and benign simple cortical cysts (PAS stain supports)

Adrenal Gland:

See part 3

Lymph Nodes:

See parts 2 & 4

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

[page 2 of 3]
COMMENT: The tumor exhibits predominant papillary features with focal solid and clear cell morphology. Tumor cells have large eosinophilic to clear cytoplasm and pleomorphic nuclei with open chromatin and occasional nucleoli. By immunostains, the tumor was reactive with CD10 and CA-IX but negative for AE1:AE3, EMA, CK7 and racemase. Staining for TFE3 and TFEB (for translocation renal cell carcinomas) was also negative. This overlapping morphology and immunoprofile does not allow for placing this tumor in any of the well recognized categories and is thus designated UNCLASSIFIED TYPE. The morphology along with the presence of an angiomatous lesion, however, is reminiscent of tumors that we encountered in patients with tuberous sclerosis. This case was reviewed at [REDACTED]

2. SP: Lymph nodes, pre-aortic and para-aortic, dissection:

Lymph Nodes:

Not involved

Number of nodes examined: 17

Segment of benign ureter

3. SP: Adrenal gland and supra-hilar lymph node, left, excision:

Benign adrenal gland and periadrenal adipose tissue

No lymph nodes identified

4. SP: Lymph nodes, left hilar, dissection:

Lymph Nodes:

Not involved

Number of nodes examined: 4

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are [REDACTED] should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement [REDACTED] is qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Special Studies:

Result	Special Stain	Comment
	CA-1X.	
	CD10	
	AE1:AE3	
	EMA	
	CK7	
	CD117	
	RACEMASE	
	IMM H&E	
	IMM RECUT	
	PAS	
	NEG CONT	
	HMB-45	
	A103-I	
	HMB-45	
	A103-I	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	NEG CONT	

Gross Description:

1) The specimen is received from [REDACTED] labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 812 g in total measuring 22 x 13 x 8 cm overall. The kidney measures 12.2 x 9 x 4 cm. The attached ureter measures 7 cm in length and 0.6 cm in diameter. The attached renal vein measures 2 cm in length and 1 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and

[page 3 of 3]
bivalved to reveal a hemorrhagic golden yellow and red tumor at mid portion measuring 6.5 x 6 x 4.5 cm. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. There is a second nodule in the lower pole measuring 1 x 0.6 x 0.6 cm showing a tan gray cut surface. The cortex measures 1 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections: UM -- ureteral margin, VM- vascular margin, T- tumor, TSF -- tumor with sinus fat
RP -- renal pelvis representative sections, K -- representative sections kidney, T2- second cortical nodule

2). The specimen is received in formalin, labeled "preaortic and para-aortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 3.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN -- lymph nodes, BLN -- bisected lymph nodes, QLN -- quadrisected lymph node

3) The specimen is received fresh labeled as "Left adrenal gland suprahilar lymph node" and consists of a fragmented piece of adipose tissue measuring 9 x 7.5 x 1.5 cm, containing an adrenal gland measuring 6 x 3.5 x 1 cm. The cut section of adrenal reveals a golden yellow cortex and dark brown medulla, which is grossly unremarkable. The specimen is representatively submitted as follows. Summary of Sections: A- adrenal, F-fat

4). The specimen is received in formalin, labeled "hilar lymph node, left" and consists of four pink tan firm lymph nodes ranging from 0.5 to 1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN -- lymph nodes, BLN -- bisected lymph node

Summary of Sections:

Part 1: SP: Kidney, left, total nephrectomy

Block	Sect. Site	PCs
2	k	2
2	rp	2
7	t	7
3	t2	3
5	tsf	5
1	um	1
1	vm	1

Part 2: SP: Lymph nodes, preaortic and para-aortic, dissection

Block	Sect. Site	PCs
3	BLN	4
7	LN	13
4	QLN	4

Part 3: SP: Adrenal gland and suprahilar lymph node, left, excision

Block	Sect. Site	PCs
2	ad	2
3	f	3

Part 4: SP: Lymph nodes, left hilar, dissection

Block	Sect. Site	PCs
1	BLN	2
2	LN	3

Source: NCI Genomic Data Commons file 0ca0e949-610e-45b1-ba23-8366e867f9ed (TCGA-BQ-5892.7B3D8D0A-6422-42C4-8BF2-D57A18D2D729.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).